Somatic mutation profile of tumor specimen C3N-00324-04 (aliquot CPT0010820006) from CPTAC case C3N-00324, project CPTAC-3 (Uterus, NOS — Adenomas and Adenocarcinomas). Sex at birth: female; Vital status: Alive; Primary diagnosis: Endometrioid adenocarcinoma, NOS; Tissue or organ of origin: Uterus, NOS; AJCC pathologic stage: Stage II; FIGO stage: Stage II; Tumor grade: G2; Age at diagnosis: 66.5 years (24,280 days).
Specimen C3N-00324-04: Sample type: Primary Tumor; Tissue type: Tumor; Tumor descriptor: Primary; Specimen type: Solid Tissue; Biospecimen anatomic site: Uterus; Preservation method: Snap Frozen.
Source: NCI Genomic Data Commons open-access Masked Somatic Mutation file (Mutation Annotation Format, MAF) 1ed69aae-d5ac-4ac3-ba34-66c3d9ea0efc.wxs.aliquot_ensemble_masked.maf.gz, workflow Aliquot Ensemble Somatic Variant Merging and Masking; Data Release 46.0 - August 10, 2026. Variants were called in the tumor against matched normal specimen C3N-00324-31 (Blood Derived Normal), aliquot CPT0010950002; read counts below are tumor reads.
https://portal.gdc.cancer.gov/files/60a768a5-8ed9-4fa5-bf00-e2a6a7196934

The open-access MAF lists 102 somatic variants for this specimen: 73 protein-altering or splice-affecting, 18 silent, 11 other (UTR, intronic, flanking, RNA and similar).
By variant classification: Missense Mutation 58, Silent 18, Intron 5, In Frame Del 4, RNA 4, Frame Shift Del 4, Nonsense Mutation 3, Frame Shift Ins 2, In Frame Ins 1, 3'UTR 1, 5'UTR 1, Splice Site 1.

Variants (all; order: hotspot or ClinVar-pathogenic variants first, then other protein-altering variants with a dbSNP/COSMIC/ClinVar record ('catalogued as' / 'ClinVar'), then the remaining protein-altering, then silent, then non-coding — alphabetical by gene within each group; each line: gene | DNA and protein change | classification | tumor variant allele fraction (VAF) | annotations). Protein positions are numbered on GDC's canonical Ensembl transcript (GENCODE v36); where an older RefSeq transcript numbers the protein differently, the line names both transcripts and gives that numbering too:
- ARID1A | c.2077C>T p.R693* | Nonsense Mutation (SNP) | VAF 42/269 reads (16%) | hotspot (GDC flag); catalogued as COSV61375361; called by muse, mutect2, varscan2
- FGFR2 | c.1975A>G p.K659E | Missense Mutation (SNP) | VAF 48/308 reads (16%) | SIFT deleterious (0); PolyPhen probably damaging (0.987); catalogued as rs1057519795, COSV60638890; ClinVar: likely pathogenic; called by muse, mutect2, varscan2
- KMT2B | c.521del p.P174Qfs*20 | Frame Shift Del (DEL) | VAF 32/110 reads (29%) | catalogued as rs763183959; ClinVar: pathogenic; called by mutect2, varscan2
- PIK3CA | c.3140A>G p.H1047R | Missense Mutation (SNP) | VAF 28/145 reads (19%) | hotspot (GDC flag); SIFT tolerated (0.11); PolyPhen benign (0.085); catalogued as rs121913279, CM153086, COSV55873195, COSV55873401, COSV55888015; ClinVar: pathogenic / likely pathogenic; called by muse, mutect2, varscan2
- PPP2R1A | c.547C>T p.R183W | Missense Mutation (SNP) | VAF 29/161 reads (18%) | hotspot (GDC flag); SIFT deleterious (0); PolyPhen probably damaging (0.996); catalogued as rs1057519946, COSV59042187, COSV59042498; ClinVar: likely pathogenic; called by muse, mutect2, varscan2
- PTEN | c.276C>G p.D92E | Missense Mutation (SNP) | VAF 65/332 reads (20%) | hotspot (GDC flag); SIFT deleterious (0); PolyPhen probably damaging (0.998); catalogued as CM033666, COSV64288954, COSV64292660; called by muse, mutect2, varscan2
- PTEN | c.877G>T p.G293* | Nonsense Mutation (SNP) | VAF 42/206 reads (20%) | catalogued as rs878853944, COSV64306603; ClinVar: pathogenic; called by muse, mutect2, varscan2
- ADAMTS9 | c.2698C>T p.R900* | Nonsense Mutation (SNP) | VAF 20/130 reads (15%) | catalogued as rs780201945, COSV55781637; called by muse, mutect2, varscan2
- AJUBA | c.479A>G p.N160S | Missense Mutation (SNP) | VAF 27/178 reads (15%) | SIFT deleterious (0); PolyPhen benign (0.003); catalogued as rs1192844186; called by muse, mutect2, varscan2
- ASXL3 | c.4544C>T p.A1515V | Missense Mutation (SNP) | VAF 20/131 reads (15%) | SIFT deleterious, low confidence (0.03); PolyPhen benign (0.019); catalogued as rs370461495, COSV99324430; called by muse, mutect2, varscan2
- BLK | c.757G>A p.G253S | Missense Mutation (SNP) | VAF 86/485 reads (18%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as rs565575821; called by muse, mutect2, varscan2
- CADPS2 | c.2077C>T p.L693F | Missense Mutation (SNP) | VAF 24/171 reads (14%) | SIFT deleterious (0); PolyPhen probably damaging (0.995); catalogued as rs778313912; called by muse, mutect2, varscan2
- CCBE1 | c.484C>T p.R162W | Missense Mutation (SNP) | VAF 72/349 reads (21%) | SIFT deleterious (0); PolyPhen possibly damaging (0.745); catalogued as rs562613006, COSV101232765, COSV101232793; called by muse, mutect2, varscan2
- CNTNAP3 | c.1987G>A p.A663T | Missense Mutation (SNP) | VAF 50/294 reads (17%) | SIFT tolerated (0.53); PolyPhen benign (0.015); catalogued as rs769642592; called by muse, mutect2, varscan2
- CRIP1 | c.139G>A p.E47K | Missense Mutation (SNP) | VAF 48/245 reads (20%) | SIFT tolerated (0.18); PolyPhen benign (0.013); catalogued as rs369446226; called by muse, mutect2, varscan2
- DCT | c.359G>A p.R120Q | Missense Mutation (SNP) | VAF 48/219 reads (22%) | SIFT tolerated (1); PolyPhen benign (0); catalogued as rs576397146, COSV65469620; called by muse, mutect2, varscan2
- DNALI1 | c.497C>T p.A166V (on ENST00000296218; = p.A144V on NM_003462.5) | Missense Mutation (SNP) | VAF 22/119 reads (18%) | SIFT deleterious (0); PolyPhen benign (0.099); catalogued as rs1275645906; called by muse, mutect2, varscan2
- DNMT3B | c.2348_2349del p.Q783Rfs*21 | Frame Shift Del (DEL) | VAF 48/343 reads (14%) | catalogued as rs1368779496; called by mutect2, pindel, varscan2
- EFCAB13 | c.2728T>C p.C910R | Missense Mutation (SNP) | VAF 23/97 reads (24%) | SIFT deleterious, low confidence (0.03); PolyPhen possibly damaging (0.452); catalogued as rs1435656574; called by muse, mutect2, varscan2
- EMX1 | c.811C>T p.R271W | Missense Mutation (SNP) | VAF 36/240 reads (15%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as rs1037079323, COSV99252365; called by muse, mutect2, varscan2
- FAM47B | c.1630G>A p.G544R | Missense Mutation (SNP) | VAF 29/201 reads (14%) | SIFT deleterious (0.05); PolyPhen benign (0.367); catalogued as COSV61456392; called by muse, mutect2, varscan2
- GPRC5A | c.602G>T p.G201V | Missense Mutation (SNP) | VAF 24/201 reads (12%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as rs1168324742; called by muse, mutect2, varscan2
- GRM3 | c.526G>A p.A176T | Missense Mutation (SNP) | VAF 26/138 reads (19%) | SIFT tolerated (0.16); PolyPhen probably damaging (0.919); catalogued as COSV64468590; called by muse, mutect2, varscan2
- KCTD17 | c.176G>T p.R59L | Missense Mutation (SNP) | VAF 29/93 reads (31%) | SIFT deleterious (0.03); PolyPhen probably damaging (0.935); catalogued as rs1250680602; called by muse, mutect2, varscan2
- KRT73 | c.1367C>T p.S456L | Missense Mutation (SNP) | VAF 13/73 reads (18%) | SIFT deleterious (0); PolyPhen benign (0.354); catalogued as rs370258682; called by muse, mutect2, varscan2
- MED20 | c.610C>A p.Q204K | Missense Mutation (SNP) | VAF 13/125 reads (10%) | SIFT tolerated (0.18); PolyPhen possibly damaging (0.628); catalogued as COSV54825003; called by muse, varscan2
- NLRP9 | c.1247G>A p.R416Q | Missense Mutation (SNP) | VAF 34/202 reads (17%) | SIFT deleterious (0.04); PolyPhen probably damaging (0.928); catalogued as rs747911398, COSV60461087, COSV60465744; called by muse, mutect2, varscan2
- NTN1 | c.1745G>A p.R582Q | Missense Mutation (SNP) | VAF 44/245 reads (18%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.663); catalogued as rs754203987; called by muse, mutect2, varscan2
- PDE4B | c.166T>A p.S56T | Missense Mutation (SNP) | VAF 46/329 reads (14%) | SIFT tolerated, low confidence (0.4); PolyPhen benign (0.034); catalogued as COSV58473137; called by muse, mutect2, varscan2
- PLA2G4C | c.1204C>T p.R402W | Missense Mutation (SNP) | VAF 41/153 reads (27%) | SIFT deleterious (0.02); PolyPhen benign (0.198); catalogued as rs777098708; called by muse, mutect2, varscan2
- PTEN | c.485A>T p.D162V | Missense Mutation (SNP) | VAF 36/208 reads (17%) | SIFT deleterious (0); PolyPhen probably damaging (0.985); catalogued as COSV64290065, COSV64301645; called by muse, mutect2, varscan2
- RBMXL2 | c.779G>A p.R260Q | Missense Mutation (SNP) | VAF 27/162 reads (17%) | SIFT tolerated (0.07); PolyPhen probably damaging (0.982); catalogued as rs1441385521; called by muse, mutect2, varscan2
- RP1L1 | c.1153C>T p.R385W | Missense Mutation (SNP) | VAF 37/244 reads (15%) | SIFT deleterious (0.02); PolyPhen possibly damaging (0.887); catalogued as rs765247276, COSV66751438; called by muse, mutect2, varscan2
- SI | c.3896C>A p.A1299E | Missense Mutation (SNP) | VAF 43/211 reads (20%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as rs1559990008; ClinVar: uncertain significance; called by muse, mutect2, varscan2
- SIX3 | c.199G>A p.G67S | Missense Mutation (SNP) | VAF 9/89 reads (10%) | SIFT tolerated (0.75); PolyPhen benign (0); catalogued as COSV99578352; called by muse, mutect2
- SLC17A6 | c.173C>T p.P58L | Missense Mutation (SNP) | VAF 10/304 reads (3%) | SIFT deleterious (0.04); PolyPhen benign (0.397); catalogued as COSV99581005; called by muse, mutect2
- SLC25A46 | c.908C>G p.T303S | Missense Mutation (SNP) | VAF 39/195 reads (20%) | SIFT tolerated (1); PolyPhen benign (0); catalogued as COSV100582659; called by muse, mutect2, varscan2
- SRSF4 | c.698G>A p.R233Q | Missense Mutation (SNP) | VAF 50/188 reads (27%) | SIFT deleterious (0.03); PolyPhen possibly damaging (0.551); catalogued as rs758539230; called by muse, mutect2
- TAT | c.715C>T p.R239W | Missense Mutation (SNP) | VAF 57/349 reads (16%) | SIFT deleterious (0); PolyPhen possibly damaging (0.893); catalogued as rs779258482; called by muse, mutect2, varscan2
- TECTA | c.4471G>A p.G1491S | Missense Mutation (SNP) | VAF 71/342 reads (21%) | SIFT deleterious (0.03); PolyPhen probably damaging (1); catalogued as rs727503463; ClinVar: uncertain significance; called by muse, mutect2, varscan2
- TMEM132B | c.524G>A p.R175Q | Missense Mutation (SNP) | VAF 39/186 reads (21%) | SIFT tolerated (0.19); PolyPhen benign (0.029); catalogued as rs770384484, COSV54742901; called by muse, mutect2, varscan2
- TMEM94 | c.1457G>T p.R486L | Missense Mutation (SNP) | VAF 75/323 reads (23%) | SIFT tolerated (0.58); PolyPhen benign (0.02); catalogued as COSV58594406; called by muse, mutect2, varscan2
- UNG | c.527C>T p.P176L (on ENST00000242576 / NM_080911.3; = p.P167L on NM_003362.4) | Missense Mutation (SNP) | VAF 90/419 reads (21%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.998); catalogued as rs970951562; called by muse, mutect2, varscan2
- ZNF613 | c.336_338del p.I113del (on ENST00000293471 / NM_001031721.4; = p.I77del on NM_024840.4) | In Frame Del (DEL) | VAF 8/54 reads (15%) | catalogued as rs756016828; called by pindel, varscan2
- ZNF614 | c.1272G>T p.E424D | Missense Mutation (SNP) | VAF 18/226 reads (8%) | SIFT deleterious (0.04); PolyPhen probably damaging (0.985); catalogued as COSV99571851; called by muse, mutect2
- AGAP9 | c.1042G>A p.A348T | Missense Mutation (SNP) | VAF 72/1226 reads (6%) | SIFT tolerated (0.08); PolyPhen probably damaging (0.964); called by muse, mutect2
- AKAP6 | c.5330C>T p.S1777F | Missense Mutation (SNP) | VAF 38/226 reads (17%) | SIFT deleterious (0); PolyPhen probably damaging (0.996); called by muse, mutect2, varscan2
- AR | c.992dup p.A332Cfs*9 | Frame Shift Ins (INS) | VAF 49/299 reads (16%) | called by mutect2, pindel, varscan2
- ARID1A | c.6033_6044del p.G2012_I2015del | In Frame Del (DEL) | VAF 33/227 reads (15%) | called by mutect2, pindel, varscan2
- ARID5B | c.1376del p.P459Qfs*20 | Frame Shift Del (DEL) | VAF 26/141 reads (18%) | called by mutect2, pindel, varscan2
- ASIC2 | c.727G>A p.G243R | Missense Mutation (SNP) | VAF 19/154 reads (12%) | SIFT deleterious (0); PolyPhen probably damaging (1); called by muse, mutect2, varscan2
- CCDC60 | c.171-8_184del p.X57_splice | Splice Site (DEL) | VAF 8/72 reads (11%) | called by mutect2, pindel
- CGREF1 | c.466C>G p.L156V | Missense Mutation (SNP) | VAF 50/351 reads (14%) | SIFT tolerated (0.26); PolyPhen benign (0.037); called by muse, mutect2, varscan2
- COL12A1 | c.8710_8712dup p.M2904dup | In Frame Ins (INS) | VAF 34/221 reads (15%) | called by mutect2, pindel, varscan2
- CSH2 | c.293A>C p.N98T | Missense Mutation (SNP) | VAF 42/238 reads (18%) | SIFT deleterious (0.03); PolyPhen probably damaging (1); called by muse, varscan2
- FANCD2 | c.3985G>A p.E1329K | Missense Mutation (SNP) | VAF 72/396 reads (18%) | SIFT tolerated (1); PolyPhen benign (0.007); called by muse, mutect2, varscan2
- GLRA4 | c.246C>A p.F82L | Missense Mutation (SNP) | VAF 19/144 reads (13%) | SIFT deleterious (0.01); PolyPhen benign (0.402); called by muse, mutect2, varscan2
- HBA2 | c.211G>A p.V71M | Missense Mutation (SNP) | VAF 20/556 reads (4%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.931); called by muse, mutect2
- KIAA0232 | c.3289T>C p.Y1097H | Missense Mutation (SNP) | VAF 36/322 reads (11%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); called by muse, mutect2, varscan2
- MECOM | c.2251C>T p.H751Y (on ENST00000468789 / NM_001105078.4; = p.H939Y on NM_004991.4) | Missense Mutation (SNP) | VAF 18/211 reads (9%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); called by muse, mutect2
- MYL1 | c.296G>A p.S99N | Missense Mutation (SNP) | VAF 24/161 reads (15%) | SIFT tolerated (0.06); PolyPhen benign (0.013); called by muse, mutect2, varscan2
- NFE2L2 | c.101_103del p.R34_E35delinsQ | In Frame Del (DEL) | VAF 25/160 reads (16%) | called by mutect2, pindel, varscan2
- OR1A1 | c.243G>T p.M81I | Missense Mutation (SNP) | VAF 41/210 reads (20%) | SIFT tolerated (0.06); PolyPhen benign (0.03); called by muse, mutect2, varscan2
- PCBP1 | c.302_337del p.R101_L112del | In Frame Del (DEL) | VAF 19/183 reads (10%) | called by mutect2, pindel
- PEX26 | c.305T>G p.V102G | Missense Mutation (SNP) | VAF 85/427 reads (20%) | SIFT deleterious (0); PolyPhen possibly damaging (0.842); called by muse, mutect2, varscan2
- RNPEPL1 | c.526G>A p.A176T | Missense Mutation (SNP) | VAF 32/147 reads (22%) | SIFT deleterious (0.03); PolyPhen benign (0.029); called by muse, mutect2, varscan2
- SOX9 | c.1526dup p.*510Lfs*68 | Frame Shift Ins (INS) | VAF 74/538 reads (14%) | called by mutect2, pindel, varscan2
- TJP1 | c.1148C>T p.P383L | Missense Mutation (SNP) | VAF 12/62 reads (19%) | SIFT deleterious (0.02); PolyPhen possibly damaging (0.859); called by muse, mutect2, varscan2
- TLR2 | c.586T>C p.S196P | Missense Mutation (SNP) | VAF 39/147 reads (27%) | SIFT tolerated (0.1); PolyPhen benign (0.005); called by muse, mutect2, varscan2
- TUBB4A | c.425G>T p.G142V | Missense Mutation (SNP) | VAF 59/327 reads (18%) | SIFT deleterious, low confidence (0); PolyPhen probably damaging (1); called by muse, mutect2, varscan2
- UQCRFS1 | c.40G>T p.V14F | Missense Mutation (SNP) | VAF 18/97 reads (19%) | SIFT tolerated (0.58); PolyPhen benign (0.007); called by muse, mutect2, varscan2
- ZDHHC5 | c.93_94del p.F32Cfs*45 | Frame Shift Del (DEL) | VAF 39/211 reads (18%) | called by mutect2, pindel, varscan2
- ZNF678 | c.862A>G p.T288A | Missense Mutation (SNP) | VAF 30/193 reads (16%) | SIFT deleterious (0.04); PolyPhen possibly damaging (0.536); called by muse, mutect2, varscan2
- AOC1 | c.1167C>T p.I389= | Silent (SNP) | VAF 45/204 reads (22%) | catalogued as COSV62868241; called by muse, mutect2, varscan2
- CFHR3 | c.126C>T p.Y42= | Silent (SNP) | VAF 71/328 reads (22%) | catalogued as COSV66403135; called by muse, mutect2, varscan2
- DOCK11 | c.600C>T p.D200= | Silent (SNP) | VAF 18/109 reads (17%) | called by muse, mutect2, varscan2
- GHR | c.921A>G p.K307= | Silent (SNP) | VAF 25/230 reads (11%) | called by muse, mutect2, varscan2
- LAIR1 | c.291G>A p.G97= | Silent (SNP) | VAF 38/184 reads (21%) | called by muse, mutect2, varscan2
- LUZP4 | c.42G>A p.P14= | Silent (SNP) | VAF 26/180 reads (14%) | catalogued as rs782550737, COSV64218539; called by muse, mutect2, varscan2
- M1AP | c.133C>T p.L45= | Silent (SNP) | VAF 43/369 reads (12%) | called by muse, mutect2, varscan2
- MMP1 | c.810C>T p.I270= | Silent (SNP) | VAF 25/215 reads (12%) | catalogued as rs929189649, COSV59509650; called by muse, varscan2
- MYL4 | c.303C>T p.P101= | Silent (SNP) | VAF 18/117 reads (15%) | called by muse, mutect2
- MYO7B | c.4899C>T p.P1633= | Silent (SNP) | VAF 22/100 reads (22%) | called by muse, mutect2, varscan2
- PRKN | c.702G>T p.R234= | Silent (SNP) | VAF 66/339 reads (19%) | called by muse, mutect2, varscan2
- RBL1 | c.2478C>T p.F826= | Silent (SNP) | VAF 23/111 reads (21%) | catalogued as COSV60333789; called by muse, mutect2, varscan2
- RIPK2 | c.424T>C p.L142= | Silent (SNP) | VAF 21/99 reads (21%) | called by muse, mutect2, varscan2
- SOX12 | c.219C>T p.R73= | Silent (SNP) | VAF 47/251 reads (19%) | called by muse, mutect2, varscan2
- SOX7 | c.732G>A p.P244= | Silent (SNP) | VAF 14/78 reads (18%) | catalogued as rs775718343, COSV100449221, COSV58731290; called by muse, mutect2, varscan2
- TIE1 | c.567G>C p.S189= | Silent (SNP) | VAF 31/187 reads (17%) | catalogued as COSV100992044; called by muse, mutect2, varscan2
- TSPEAR | c.1833C>T p.F611= | Silent (SNP) | VAF 44/208 reads (21%) | catalogued as rs1555911663; called by muse, varscan2
- UNK | c.1725A>G p.A575= | Silent (SNP) | VAF 17/110 reads (15%) | called by muse, mutect2, varscan2
- AC011410.1 | n.348C>T | RNA (SNP) | VAF 24/116 reads (21%) | catalogued as rs568836242; called by muse, mutect2
- CUX1 | c.1384-48G>A | Intron (SNP) | VAF 23/93 reads (25%) | catalogued as rs1258069504; called by muse, mutect2, varscan2
- FOXP2 | c.*1821T>C | 3'UTR (SNP) | VAF 24/111 reads (22%) | called by muse, mutect2, varscan2
- GNB5 | c.627+1186A>G | Intron (SNP) | VAF 14/73 reads (19%) | called by muse, mutect2, varscan2
- MIR519A2 | n.21C>T | RNA (SNP) | VAF 32/198 reads (16%) | called by muse, mutect2, varscan2
- NOC2LP2 | n.1149G>T | RNA (SNP) | VAF 60/342 reads (18%) | called by muse, mutect2, varscan2
- RPL14 | c.3+163G>T | Intron (SNP) | VAF 33/171 reads (19%) | called by muse, mutect2, varscan2
- RPL14 | c.3+164C>T | Intron (SNP) | VAF 32/171 reads (19%) | called by muse, mutect2, varscan2
- SPATA31C2 | n.1648G>A | RNA (SNP) | VAF 34/334 reads (10%) | called by muse, mutect2, varscan2
- TP53AIP1 | c.141+11G>T | Intron (SNP) | VAF 67/251 reads (27%) | called by muse, mutect2, varscan2
- VPS11 | c.-912C>T | 5'UTR (SNP) | VAF 38/291 reads (13%) | catalogued as rs781805086; called by muse, mutect2, varscan2
